Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A16X, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A16X-01A (Primary Tumor).

[page 1 of 6]
Surgical Pathology

Site Code: Endometrium
C54.1**DIAGNOSIS:**

A.Uterus, tubes and ovaries, hysterectomy and salpingo-oophorectomy: FIGO grade II (of III) endometrial adenocarcinoma, endometrioid type, forming a 2.3 x 2.0 x 0.8 cm mass

at the right posterior of uterine fundus. The tumor invades 0.4 cm of myometrium with a 2.2 cm myometrium thickness. The lower uterine segment and cervix are not involved by tumor. The bilateral ovaries and fallopian tubes are without diagnostic abnormality.

C, D, E, F.Lymph nodes, left pelvic, excision: Multiple left pelvic lymph nodes (6 external iliac, 2 internal iliac, 5 common iliac, 5 obturator) are negative for tumor.

G, H, I, J.Lymph nodes, right pelvic, excision: Multiple right pelvic lymph nodes (7 external iliac, 5 internal iliac, 4 common iliac, 12 obturator) are negative for tumor.

K, N.Gonadal vessels, left and right, excision: The left and right gonadal vessels identified; negative for tumor.

L, O.Lymph nodes, left and right para-aortic, excision: Multiple para-aortic lymph nodes above the inferior mesenteric artery (6 left, 8 right) are negative for tumor.

M, P.Lymph nodes, left and right para-aortic, excision: Multiple para-aortic lymph nodes below the inferior mesenteric artery (6 left, 6 right) are negative for tumor.

B.Margin, lower anterior cervix, excision: Negative for tumor.

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the

[page 2 of 6]
specimen(s).

GROSS DESCRIPTION:

A. Received fresh labeled "uterus tubes and ovaries" is a 120 gram uterus with attached bilateral tubes and ovaries and unremarkable cervix. The uterine serosa is smooth. There is a 2.3 x 2.0 x 0.8 cm mass in the right posterior endometrium of the endometrial cavity with 2.2 cm myometrial thickness. There is a 2.6 x 1.5 x 1.0 cm right ovary with a smooth solid cut surface with a 3.1 x 0.5 cm right fallopian tube. There is a 3.2 x 1.1 x 1.0 cm left ovary with a smooth outer surface and a solid cut surface with a 5.1 x 0.5 left fallopian tube.

B. Received fresh labeled "lower margin anterior cervix" is a 2.6 x 0.5 x 0.4 cm portion of solid type, without orientation. Margin submitted.

C. Received fresh labeled "left pelvic external lymph nodes" is a 7.5 x 6.0 x 1.8 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

D. Received fresh labeled "left pelvic internal lymph nodes" is a 3.0 x 2.5 x 0.5 cm aggregate of adipose tissue, lymphatic tissue not identified grossly. All lymphatic tissue submitted. Grossed by

E. Received fresh labeled "left pelvic obturator lymph nodes" is a 4.5 x 3.0 x 1.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

[page 3 of 6]
F. Received fresh labeled "left pelvic common" is a 4.7 x 1.5 x

0.6 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

G. Received fresh labeled "right pelvic internal lymph nodes" is

a 3.6 x 1.0 x 0.9 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

H. Received fresh labeled "right pelvic external lymph nodes" is

a 7.9 x 3.9 x 1.4 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

I. Received fresh labeled "right pelvic common lymph nodes" is a

3.0 x 1.2 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

J. Received fresh labeled "right pelvic obturator lymph nodes"

is a 4.6 x 3.2 x 1.4 cm aggregate of adipose and lymphatic tissue.

All lymphatic tissue submitted.

K. Received fresh labeled "right gonadal vessels" is a 6.4 cm in

length by 0.8 in diameter portion of unremarkable blood vessel.

Representative sections submitted.

L. Received fresh labeled "right paraaortic above inferior mesenteric artery nodes" is a 3.0 x 1.3 x 1.3 cm aggregate of

adipose and lymphatic tissue. All lymphatic tissue submitted.

M. Received fresh labeled "right paraaortic below inferior mesenteric artery nodes" is a 3.7 x 2.1 x 1.0 cm aggregate of

[page 4 of 6]
adipose and lymphatic tissue. All lymphatic tissue submitted.

N. Received fresh labeled "left gonadal vessels" is a 6.2 cm in length by 0.5 in diameter portion of unremarkable blood vessel.

Representative sections submitted.

O. Received fresh labeled "left paraaortic above inferior mesenteric artery nodes" is a 3.0 x 2.1 x 0.9 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

P. Received fresh labeled "left paraaortic below inferior mesenteric artery nodes" is a 4.2 x 2.6 x 0.9 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

BLOCK SUMMARY:

Part A: Uterus, tubes, ovaries

- 1 Endometrium
- 2 Endometrium
- 3 Endometrium
- 4 Endometrium
- 5 Left ovary
- 6 Left fallopian tube
- 7 Right fallopian tube
- 8 Right ovary
- 9 Cervix at 6:00
- 10 Myometrium

Part B: Lower margin anterior cervix

- 1 Lower margin Ant cervix

Part C: Left pelvic lymph node external

- 1 Lt Ext pelvic LN 1
- 2 Left Ext pelvic LN 3
- 3 Left Ext pelvic LN 1
- 4 Left Ext pelvic LN 1

Part D: Left pelvic lymph node internal

- 1 Lt internal LNS ?

[page 5 of 6]
Part E: Left pelvic lymph node obturator
1 Left Obt pelvic LN 2
2 Left Obt pelvic LN 3

Part F: Left pelvic lymph node common
1 Lt common LNS 3
2 Lt common LNS 3

Part G: Right pelvic lymph node internal
1 Rt internal LNS 5
2 Rt internal LNS 2

Part H: Right pelvic lymph node external
1 Rt external LNS 3
2 Rt external LNS 2
3 Rt external LN 1
4 Rt external LN 1

Part I: Right pelvic lymph node common
1 Rt common LNS 4
2 Rt common LN 1

Part J: Right pelvic lymph node obturator
1 Rt obturator LN 1
2 Rt oburator LNS 2
3 Rt obturator LN 1
4 Rt obturator LNS 4
5 Rt obturator LNS 4
6 Rt oburator LNS 5
7 Rt oburator LNS 5

Part K: Right Gonadal vessels
1 Rt gonadal vessels

Part L: Right Para-aortic Nodes above IMA
1 Rt PA above IMA LNS 4
2 Rt PA above IMA LNS 4
3 Rt PA above IMA LN 1

Part M: Right Para-aortic Nodes below IMA
1 Rt PA below IMA LNS 3
2 Rt PA below IMA LN 1

Part N: Left gonadal vessels
1 Lt gonadal vessels

Part O: Left Para-aortic Lymph Nodes above IMA

[page 6 of 6]
- 1 Lt PA above IMA LNS 3
- 2 Lt PA above IMA LNS 3

Part P: Left Para-aortic Lymph Nodes below IMA

- 1 Lt PA below IMA LNS 2
- 2 Lt PA below IMA LNS 2
- 3 Lt PA below IMA LNS 3

41P-20 Discrepancy		/
Don't/Synchronous Primary Noted		/

Source: NCI Genomic Data Commons file cff01b9b-7b77-4b3b-b27d-492b7bdba465 (TCGA-D1-A16X.0C395D2C-1864-448E-8FB7-09BFE5FF4C50.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).